Somatic mutation profile of tumor specimen TCGA-06-6390-01A (aliquot TCGA-06-6390-01A-11D-1696-08) from TCGA case TCGA-06-6390, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.4 years (21,328 days).
Specimen TCGA-06-6390-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12fb7f02-ce1a-45ad-8f5d-a732ab066033.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6390-10A (Blood Derived Normal), aliquot TCGA-06-6390-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9530104-a89a-48ea-8e46-7d3b8fe40a12

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 30, Silent 14, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CATSPERZ | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.066); catalogued as rs376949802; called by mutect2, varscan2
- DNAH2 | c.10153G>A p.V3385I | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as rs758341170, COSV66717463; called by muse, mutect2, varscan2
- ELAPOR2 | c.2597A>G p.Y866C (on ENST00000450689 / NM_001142749.3; = p.Y699C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs752737169; called by muse, mutect2, varscan2
- EPPK1 | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs782758450; called by muse, mutect2, varscan2
- EPS15L1 | c.988A>G p.K330E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs1002157110; called by muse, mutect2, varscan2
- GABRA6 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV50877559; called by muse, mutect2, varscan2
- IL21R | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61972100; called by muse, mutect2, varscan2
- KIRREL3 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1447216237, COSV69384680; called by muse, mutect2, varscan2
- LY96 | c.475T>C p.S159P | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV53026448; called by muse, mutect2, varscan2
- MEFV | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs750095575, COSV54826092; called by muse, mutect2, varscan2
- NAV3 | c.1963C>G p.P655A | Missense Mutation (SNP) | VAF 40/311 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as COSV57084598; called by muse, mutect2, varscan2
- NLRP3 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs776897356, COSV60220208; called by muse, varscan2
- NPL | c.618T>G p.S206R | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV51126775; called by muse, mutect2, varscan2
- OR9I1 | c.894A>T p.K298N | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56927292; called by muse, mutect2, varscan2
- PA2G4 | c.392A>G p.Q131R | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV57260641; called by muse, mutect2, varscan2
- PIWIL3 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 201/562 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.055); catalogued as COSV59994483; called by muse, mutect2, varscan2
- QARS1 | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.36); catalogued as rs747163409, COSV60275922; called by muse, mutect2, varscan2
- SACS | c.9858T>G p.F3286L | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.637); catalogued as rs1450060286, COSV66545588, COSV66548109; called by muse, mutect2, varscan2
- SH3GL2 | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV66053853; called by muse, varscan2
- SLC30A7 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV63018427; called by muse, mutect2, varscan2
- TIMM21 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as rs1184542326, COSV50054170; called by muse, mutect2, varscan2
- UBR1 | c.2570A>G p.E857G | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV51934901; called by muse, mutect2
- USP15 | c.1405C>G p.P469A (on ENST00000280377 / NM_001351159.2; = p.P440A on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54797253; called by muse, mutect2, varscan2
- VPS18 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs267604184, COSV55031879; called by muse, mutect2, varscan2
- ZNF595 | c.296T>C p.I99T | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs924994561; called by muse, mutect2, varscan2
- GABPB1 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- LILRB3 | c.519C>A p.H173Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- OR10G8 | c.914_916del p.V305del | In Frame Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
- SEPTIN14 | c.384A>G p.I128M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- TAS2R20 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF354C | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2
- ABCC5 | c.2391A>G p.K797= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs1477500059, COSV55595165; called by muse, mutect2, varscan2
- AHCTF1 | c.4041C>T p.I1347= (on ENST00000366508; = p.I1321= on NM_015446.5) | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV58253925; called by muse, mutect2, varscan2
- CLEC10A | c.855C>T p.F285= (on ENST00000254868 / NM_182906.4; = p.F261= on NM_006344.4) | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as rs780248039, COSV54702334; called by muse, mutect2, varscan2
- CYLC2 | c.210T>C p.D70= | Silent (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- FAT1 | c.900C>A p.L300= | Silent (SNP) | VAF 125/274 reads (46%) | called by muse, mutect2, varscan2
- IGFBP1 | c.426C>T p.A142= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as COSV51874309, COSV51875240; called by muse, mutect2, varscan2
- MAG | c.141G>A p.P47= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as rs1348746877, COSV62702287; called by muse, mutect2, varscan2
- MYO15A | c.8433G>A p.G2811= | Silent (SNP) | VAF 54/160 reads (34%) | catalogued as COSV52763276; called by muse, mutect2, varscan2
- POLRMT | c.705C>T p.L235= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- PRKG2 | c.1389G>T p.G463= | Silent (SNP) | VAF 104/399 reads (26%) | catalogued as COSV100019886, COSV52330346; called by muse, mutect2, varscan2
- SLC46A3 | c.264A>T p.T88= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV57182363; called by muse, varscan2
- SPATA13 | c.1608C>T p.D536= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs368299819; called by muse, mutect2, varscan2
- TTN | c.16350C>T p.S5450= (on ENST00000591111; = p.S4523= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs777677229, COSV60327857; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBA7 | c.2013G>A p.A671= | Silent (SNP) | VAF 37/188 reads (20%) | catalogued as rs766026076, COSV60968577; called by muse, mutect2, varscan2
